Surgical pathology report (de-identified scan), TCGA case TCGA-HT-7884, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-7884-01B (Primary Tumor).

Tumor Sample: [REDACTED]

Normal Sample: [REDACTED]

Microscopic Description:

Permanent section of the frozen section specimen demonstrates a moderately hypercellular glial neoplasm that diffusely infiltrates the white matter. The tumor cells demonstrate only mild atypia. No mitotic figures are seen on the frozen section material. There is no microvascular proliferation or necrosis. The tumor cells have round to oblong nuclei with small caps of eosinophilic cytoplasm.

Sections demonstrate a mildly hypercellular glial neoplasm that diffusely infiltrates the gray and white matter. The tumor cells have round to oval nuclei without significant atypia. Perinuclear halos are not seen but many tumor cells have a few apparent processes, although the majority have a microgemistocytic phenotype. Tumor cells do have a more fibrillary astrocytic appearance. Mitotic figures are not identified. There is no microvascular proliferation or necrosis.

Addendum Discussion:

Numerous cells are immunoreactive for p53 supporting an astrocytoma phenotype rather than oligodendroglioma. Scattered MIB-1 reactive cells are present. In the most proliferative areas, a labeling index of 2.5% is calculated, consistent with the low grade histologic features.

Addendum Diagnosis:

Well differentiated astrocytoma (WHO grade II)

MIB-1 Labeling Index= 2.5%

Source: NCI Genomic Data Commons file ff3d7d86-3819-4487-b01b-5e44da05eef7 (TCGA-HT-7884.9294057D-1ABA-44D6-A756-4CB48671E45E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).